FM case AD1349 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026).
https://portal.gdc.cancer.gov/cases/ee2ae36f-13fe-4b6e-ba7c-941aeffdf193

Male, 59.1 years: diagnosis not reported by GDC; metastasis biopsied or resected from the thorax. Tumor nuclei on the sequenced sample's slide: 80% (pathologist estimate recorded by GDC). Sample type: Metastatic.
